Somatic mutation profile of tumor specimen C3N-00310-04 (aliquot CPT0009010009) from CPTAC case C3N-00310, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 84.9 years (31,016 days).
Specimen C3N-00310-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8c1328d8-7e6d-472f-87c5-c00e096a5f88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00310-31 (Blood Derived Normal), aliquot CPT0009030002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/210d10c6-61b9-416a-985c-b725a6dd333d

The open-access MAF lists 95 somatic variants for this specimen: 64 protein-altering or splice-affecting, 21 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 21, Intron 7, Splice Site 5, Frame Shift Del 3, Nonsense Mutation 2, RNA 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.340+2T>A p.X114_splice | Splice Site (SNP) | VAF 32/436 reads (7%) | hotspot (GDC flag); catalogued as CD983001, COSV56547957, COSV56551654, COSV56551713, COSV56563827; called by muse, mutect2
- ABHD12 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 37/396 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs768049980, COSV100194563; called by muse, mutect2
- CCDC39 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 12/86 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs768040797, COSV56480987; called by muse, mutect2, varscan2
- CLDN16 | c.615del p.A206Pfs*26 | Frame Shift Del (DEL) | VAF 18/187 reads (10%) | catalogued as CM060926; called by mutect2, pindel, varscan2
- CSMD3 | c.3395C>A p.P1132Q (on ENST00000297405 / NM_001363185.1; = p.P1028Q on NM_052900.3) | Missense Mutation (SNP) | VAF 15/201 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765683126; called by muse, mutect2
- DGKZ | c.2057C>G p.S686C (on ENST00000454345 / NM_001105540.2; = p.S498C on NM_003646.4) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.876); catalogued as COSV58988293; called by muse, mutect2, varscan2
- DOCK5 | c.4037C>T p.A1346V | Missense Mutation (SNP) | VAF 9/141 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV52395508, COSV52404091; called by muse, mutect2
- DOK4 | c.691G>A p.A231T | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1422790855, COSV99538313; called by muse, mutect2
- FKBP9 | c.492G>T p.Q164H | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.863); catalogued as rs796764966; called by muse, mutect2
- KEAP1 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 34/539 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1040740503, COSV50633622, COSV50635967, COSV50650015; called by muse, mutect2
- LRBA | c.1270C>T p.R424W | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs945099173; ClinVar: uncertain significance; called by muse, mutect2
- MAPKBP1 | c.3070C>T p.L1024F (on ENST00000456763 / NM_001128608.2; = p.L1018F on NM_014994.3) | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs1463119166; called by muse, mutect2
- MATN4 | c.244G>A p.V82M | Missense Mutation (SNP) | VAF 8/88 reads (9%) | PolyPhen probably damaging (1); catalogued as COSV59213028; called by muse, mutect2
- MTUS1 | c.2271G>T p.R757S | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.29); PolyPhen benign (0.382); catalogued as rs777233433; called by muse, mutect2, varscan2
- MYH14 | c.3513G>C p.E1171D | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs748451285; called by muse, mutect2
- NEXMIF | c.1382G>A p.R461H | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.023); catalogued as rs1366715373; called by muse, mutect2, varscan2
- PRKCQ | c.1607C>T p.T536M | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756942026, COSV54119832; called by muse, mutect2, varscan2
- SMARCA4 | c.3304T>C p.F1102L | Missense Mutation (SNP) | VAF 33/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV60790620; called by muse, mutect2
- TLK1 | c.587T>G p.F196C | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.784); catalogued as rs1021006550; called by muse, mutect2, varscan2
- TM4SF5 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 19/277 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV54495787; called by muse, mutect2
- ZFAND4 | c.1823A>T p.E608V | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs762806906; called by muse, mutect2
- BBS4 | c.435C>A p.Y145* | Nonsense Mutation (SNP) | VAF 25/264 reads (9%) | called by muse, mutect2
- CENPJ | c.2692+1G>C p.X898_splice | Splice Site (SNP) | VAF 6/97 reads (6%) | called by muse, mutect2
- CLCN5 | c.595G>T p.V199L | Missense Mutation (SNP) | VAF 23/146 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.411); called by muse, mutect2, varscan2
- CNPY3 | c.728G>A p.S243N | Missense Mutation (SNP) | VAF 21/176 reads (12%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COMP | c.218-1G>A p.X73_splice | Splice Site (SNP) | VAF 8/120 reads (7%) | called by muse, mutect2
- CPAMD8 | c.5272G>A p.G1758S (on ENST00000651564; = p.G1711S on NM_015692.5) | Missense Mutation (SNP) | VAF 21/161 reads (13%) | SIFT tolerated, low confidence (0.76); PolyPhen possibly damaging (0.563); called by muse, mutect2, varscan2
- DGLUCY | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 24/221 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DGUOK | c.304G>T p.E102* | Nonsense Mutation (SNP) | VAF 28/374 reads (7%) | called by muse, mutect2
- DIAPH1 | c.2473+1G>A p.X825_splice | Splice Site (SNP) | VAF 34/364 reads (9%) | called by muse, mutect2
- DPYSL5 | c.29T>A p.I10N | Missense Mutation (SNP) | VAF 14/148 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- EIPR1 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- FAM200A | c.1558T>C p.F520L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FTSJ3 | c.1819C>A p.L607I | Missense Mutation (SNP) | VAF 18/180 reads (10%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GABRA4 | c.1331C>G p.T444S | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.022); called by muse, mutect2
- GALNT7 | c.1817A>C p.K606T | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0.001); called by muse, mutect2
- GARNL3 | c.2709A>C p.K903N | Missense Mutation (SNP) | VAF 21/258 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- GATM | c.1249A>G p.T417A | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- HEATR5B | c.2833G>A p.D945N | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HOXA2 | c.14T>A p.F5Y | Missense Mutation (SNP) | VAF 33/311 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HSFX4 | c.397A>C p.N133H | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- KDM5C | c.2885del p.P962Lfs*16 | Frame Shift Del (DEL) | VAF 24/166 reads (14%) | called by mutect2, pindel, varscan2
- MRPL44 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.622); called by muse, mutect2
- NBN | c.221A>C p.Y74S | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NES | c.3646C>A p.P1216T | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2
- OR5AN1 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.01); called by muse, mutect2
- PCDH8 | c.2467A>C p.T823P | Missense Mutation (SNP) | VAF 13/146 reads (9%) | SIFT tolerated (0.47); PolyPhen benign (0.159); called by muse, mutect2
- PIGN | c.878C>G p.P293R | Missense Mutation (SNP) | VAF 11/93 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- PLA2G4D | c.488G>A p.C163Y | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PLXND1 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.071); called by muse, mutect2
- PXMP4 | c.295A>T p.T99S | Missense Mutation (SNP) | VAF 18/243 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.018); called by muse, mutect2
- R3HCC1L | c.2074+1del | Frame Shift Del (DEL) | VAF 8/77 reads (10%) | called by mutect2, pindel, varscan2
- RALYL | c.190A>C p.S64R | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.312); called by muse, mutect2
- RGL1 | c.2221A>G p.K741E (on ENST00000360851 / NM_001297672.2; = p.K776E on NM_015149.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/131 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- SEC31A | c.938C>A p.P313H | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2
- SLC6A6 | c.554C>A p.T185N | Missense Mutation (SNP) | VAF 22/212 reads (10%) | SIFT tolerated (0.91); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SLCO2A1 | c.1026T>G p.I342M | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- SPATA2L | c.250G>A p.A84T | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2
- SPDL1 | c.82T>A p.L28I | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPTBN1 | c.567-1G>T p.X189_splice | Splice Site (SNP) | VAF 13/118 reads (11%) | called by muse, mutect2, varscan2
- TBX19 | c.1157C>A p.P386Q | Missense Mutation (SNP) | VAF 38/451 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.026); called by muse, mutect2
- TSC22D1 | c.2074A>G p.I692V | Missense Mutation (SNP) | VAF 8/96 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); called by muse, mutect2
- TTN | c.48170G>A p.G16057D (on ENST00000591111; = p.G8633D on NM_003319.4) | Missense Mutation (SNP) | VAF 36/402 reads (9%) | PolyPhen probably damaging (1); called by muse, mutect2
- ZNF792 | c.1610G>A p.S537N | Missense Mutation (SNP) | VAF 14/121 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ADGRG1 | c.276C>G p.L92= | Silent (SNP) | VAF 46/596 reads (8%) | called by muse, mutect2
- ATP8B2 | c.627A>G p.V209= (on ENST00000672630; = p.V176= on NM_001005855.2) | Silent (SNP) | VAF 10/114 reads (9%) | called by muse, mutect2
- AVEN | c.544T>C p.L182= | Silent (SNP) | VAF 8/154 reads (5%) | called by muse, mutect2
- CFAP298-TCP10L | c.909T>A p.I303= | Silent (SNP) | VAF 14/147 reads (10%) | called by muse, mutect2
- FCN3 | c.336T>C p.P112= | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- FOXK2 | c.1248C>T p.I416= | Silent (SNP) | VAF 11/117 reads (9%) | catalogued as COSV100081950; called by muse, mutect2
- IL4R | c.534C>T p.T178= | Silent (SNP) | VAF 10/134 reads (7%) | called by muse, mutect2
- KDR | c.1563G>A p.A521= | Silent (SNP) | VAF 19/313 reads (6%) | catalogued as rs200769864, COSV55771803; called by muse, mutect2
- KRT7 | c.132C>T p.A44= | Silent (SNP) | VAF 20/250 reads (8%) | called by muse, mutect2
- NDUFS2 | c.456T>C p.S152= | Silent (SNP) | VAF 19/418 reads (5%) | called by muse, mutect2
- NFASC | c.2112C>T p.A704= (on ENST00000339876 / NM_001378329.1; = p.A700= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/314 reads (5%) | called by muse, mutect2
- NUP98 | c.3141G>A p.G1047= (on ENST00000359171 / NM_001365126.1; = p.G1030= on NM_016320.5 and 4 other RefSeq transcripts) | Silent (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2, varscan2
- OPRD1 | c.510C>T p.I170= | Silent (SNP) | VAF 19/230 reads (8%) | called by muse, mutect2
- PKHD1 | c.7953A>C p.L2651= | Silent (SNP) | VAF 7/103 reads (7%) | called by muse, mutect2
- POMT1 | c.714C>T p.V238= | Silent (SNP) | VAF 42/542 reads (8%) | called by muse, mutect2
- SLC26A2 | c.765A>C p.G255= | Silent (SNP) | VAF 18/151 reads (12%) | called by muse, mutect2, varscan2
- SPNS1 | c.726A>C p.P242= | Silent (SNP) | VAF 24/361 reads (7%) | called by muse, mutect2
- SRSF10 | c.192T>G p.A64= | Silent (SNP) | VAF 11/152 reads (7%) | catalogued as COSV100086941; called by muse, mutect2
- UMOD | c.417G>C p.A139= | Silent (SNP) | VAF 26/336 reads (8%) | called by muse, mutect2
- ZBED6 | c.558G>A p.R186= | Silent (SNP) | VAF 15/129 reads (12%) | catalogued as rs1401224748; called by muse, mutect2, varscan2
- ZC3H12C | c.1062T>C p.D354= | Silent (SNP) | VAF 23/245 reads (9%) | called by muse, mutect2
- ABCA13 | c.12070+74T>G | Intron (SNP) | VAF 17/139 reads (12%) | called by muse, mutect2
- AC004890.2 | n.2388G>C | RNA (SNP) | VAF 9/95 reads (9%) | called by muse, mutect2
- AC244517.10 | c.36-9071C>T | Intron (SNP) | VAF 61/890 reads (7%) | catalogued as COSV101595564; called by muse, mutect2
- BRINP2 | c.461-66T>C | Intron (SNP) | VAF 10/109 reads (9%) | called by muse, mutect2
- C7orf50 | c.130-18160G>A | Intron (SNP) | VAF 5/47 reads (11%) | called by muse, mutect2
- KAZALD1 | chr10:101067948 C>T | 3'Flank (SNP) | VAF 18/178 reads (10%) | called by muse, mutect2, varscan2
- MUC19 | n.5319G>C | RNA (SNP) | VAF 18/143 reads (13%) | called by muse, mutect2, varscan2
- PIK3CD | c.-138+2446G>A | Intron (SNP) | VAF 33/577 reads (6%) | called by muse, mutect2
- ROBO3 | c.2846+22C>T | Intron (SNP) | VAF 15/216 reads (7%) | called by muse, mutect2
- WDR38 | c.308-10G>C | Intron (SNP) | VAF 32/326 reads (10%) | called by muse, mutect2
